Gene-level copy-number profile of tumor specimen C3L-05839-02 (profiled together with C3L-05839-03, C3L-05839-04, C3L-05839-05) from CPTAC case C3L-05839, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-05839-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 47a007b4-7fc7-4c11-b661-b46f23e24513.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-05839-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/7ba596ed-10da-4b22-9654-20224cd1deb1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 46; copy number 1: 6; copy number 2: 12,250; copy number 3: 5,732; copy number 4: 30,661; copy number 5: 6,921; copy number 6: 3,238; copy number 7: 23; copy number 8: 14; copy number 10: 10.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:156,774,217–156,774,662, 1 gene: AL355297.2.
- chr6:156,776,360–156,780,455, 3 genes (within-gene range 0–2): AL355297.3, MIR4466, AL355297.1.
- chr8:7,601,004–7,601,267, 1 gene: AC134684.1.
- chr8:7,891,003–7,892,555, 1 gene: HSPD1P2.
- chr8:12,393,209–12,414,373, 2 genes: DEFB109A, AC087203.3.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr10:87,945,502–87,946,024, 1 gene (within-gene range 0–2): RPL11P3.
- chr15:30,150,872–30,513,698, 19 genes: DNM1P30, AC120045.2, AC120045.1, LINC02249, AC135731.1, RNU6-17P, AC135731.2, AC019322.4, Y_RNA, CHRFAM7A, AC019322.1, U8, AC019322.3, GOLGA8R, RN7SL196P, AC019322.2, AC127502.1, AC127502.2, AC127502.3.
- chr21:41,798,225–42,350,997, 13 genes: PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492, TFF3, TFF2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:25,593,197–26,045,413, 4 genes, copy number 10: AC009623.1, AC009623.2, AC090103.1, EBF2.
- chr8:29,527,312–29,798,492, 6 genes, copy number 10: AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
